Somatic mutation profile of tumor specimen TCGA-CR-7385-01A (aliquot TCGA-CR-7385-01A-11D-2012-08) from TCGA case TCGA-CR-7385, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 42.4 years (15,477 days).
Specimen TCGA-CR-7385-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6957f9c0-ecb7-4ff2-8841-53576ed936bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7385-10A (Blood Derived Normal), aliquot TCGA-CR-7385-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2794c217-f743-48fc-957b-04dc29a6ed27

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 24, Silent 11, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.4237C>G p.Q1413E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.115); catalogued as COSV100228783; called by muse, mutect2, varscan2
- ABCA12 | c.69+2T>A p.X23_splice | Splice Site (SNP) | VAF 138/297 reads (46%) | catalogued as COSV99789393; called by muse, varscan2
- AKAP12 | c.978G>C p.K326N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99482985; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2, varscan2
- ASTN2 | c.3081G>C p.K1027N (on ENST00000313400 / NM_001365069.1; = p.K976N on NM_014010.5) | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV56008158, COSV99940599; called by muse, mutect2, varscan2
- ATP8B3 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs759252667, COSV59546713; called by muse, mutect2, varscan2
- CWF19L2 | c.1894G>C p.D632H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99978763; called by muse, mutect2, varscan2
- DIP2A | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs755076466, COSV100595597; called by muse, mutect2, varscan2
- FAM53C | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV53512048, COSV99524306; called by muse, mutect2, varscan2
- GOLM1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.474); catalogued as COSV99974309; called by muse, mutect2, varscan2
- GPX8 | c.255T>G p.N85K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99696763; called by muse, mutect2, varscan2
- H2AC4 | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99451438; called by muse, mutect2, varscan2
- HRNR | c.2710C>G p.P904A | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as rs767212282, COSV100913295; called by muse, mutect2
- KAT8 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571328; called by muse, mutect2, varscan2
- LINGO2 | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV100430282; called by muse, mutect2, varscan2
- NAV3 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57063222; called by muse, mutect2, varscan2
- NDUFS7 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.13); catalogued as rs778260862, COSV52039490; called by muse, mutect2, varscan2
- NKTR | c.2576G>A p.R859K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs570080629, COSV99235548; called by muse, varscan2
- OR51L1 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100386384; called by muse, mutect2, varscan2
- PEX5L | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs773381607, COSV55856058, COSV99828415; called by muse, mutect2, varscan2
- PPFIA4 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs1487203049, COSV99690470; called by muse, mutect2, varscan2
- SEZ6L2 | c.1910-1G>A p.X637_splice (on ENST00000308713 / NM_001114099.3; = p.X567_splice on NM_012410.4) | Splice Site (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100435312; called by muse, mutect2
- STYX | c.257A>T p.D86V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100648280; called by muse, mutect2, varscan2
- TM7SF3 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs953725082, COSV100544754; called by muse, mutect2
- TRAF5 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54821416, COSV99807323; called by muse, mutect2, varscan2
- ZBTB7B | c.835G>A p.E279K (on ENST00000292176; = p.E313K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.191); catalogued as COSV99421044; called by muse, mutect2, varscan2
- ZNF592 | c.2804C>G p.S935* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100245806; called by muse, mutect2, varscan2
- SCN2A | c.1375del p.E459Kfs*22 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- AMBN | c.357A>G p.Q119= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as COSV100534327; called by muse, mutect2, varscan2
- AWAT1 | c.522C>T p.L174= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs770689601, COSV100997193, COSV65738413; called by muse, mutect2, varscan2
- CYTH3 | c.195G>A p.Q65= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV100641377; called by muse, mutect2, varscan2
- HRNR | c.2712C>A p.P904= | Silent (SNP) | VAF 28/210 reads (13%) | catalogued as rs1369841835, COSV64260293; called by muse, mutect2
- MAPKBP1 | c.2424G>A p.K808= (on ENST00000456763 / NM_001128608.2; = p.K802= on NM_014994.3) | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99529207; called by muse, mutect2
- MDM1 | c.27T>C p.S9= | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV100291766; called by muse, mutect2
- PRPH2 | c.549C>T p.R183= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV100028030; called by muse, mutect2, varscan2
- SMYD2 | c.213A>C p.A71= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV100873169; called by muse, mutect2, varscan2
- STAB1 | c.2742T>C p.G914= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100401522; called by muse, mutect2, varscan2
- TENM4 | c.4362C>T p.D1454= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99573135; called by muse, mutect2, varscan2
- TJAP1 | c.834G>A p.P278= (on ENST00000372445 / NM_001146016.1; = p.P268= on NM_080604.3) | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1270376836, COSV52502479; called by muse, mutect2, varscan2
